Somatic mutation profile of tumor specimen TCGA-EE-A2MJ-06A (aliquot TCGA-EE-A2MJ-06A-11D-A197-08) from TCGA case TCGA-EE-A2MJ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.1 years (23,048 days).
Specimen TCGA-EE-A2MJ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c10db1b-736f-419b-93b5-67e1445a0c29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MJ-10A (Blood Derived Normal), aliquot TCGA-EE-A2MJ-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78c368c3-7115-4821-be8d-a2b19278c630

The open-access MAF lists 2,123 somatic variants for this specimen: 1,372 protein-altering or splice-affecting, 708 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,248, Silent 708, Nonsense Mutation 92, RNA 19, Splice Site 14, Intron 14, Splice Region 10, Frame Shift Del 5, 5'UTR 3, 3'UTR 3, 5'Flank 3, Translation Start Site 2.

Variants (750 of 2,123; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768671894, CM980172, COSV54435514; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP2C8 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV64876179; called by mutect2, varscan2
- GYS2 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as rs150382575, COSV53925902; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- KRIT1 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as rs886043300, COSV60666978; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NEXMIF | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as rs878854425, COSV50022161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3721C>T p.R1241* | Nonsense Mutation (SNP) | VAF 29/179 reads (16%) | hotspot (GDC flag); catalogued as rs137854562, CM000799, COSV62191467; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV59383356; called by muse, mutect2, varscan2
- AADACL2 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV62929650; called by muse, mutect2
- AAMP | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV50306982; called by muse, mutect2
- ABCA12 | c.4781C>T p.A1594V (on ENST00000272895 / NM_173076.3; = p.A1276V on NM_015657.3) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs781131695, COSV55950474; called by muse, mutect2, varscan2
- ABCA13 | c.9485G>A p.R3162Q | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369327461; called by muse, mutect2, varscan2
- ABCB1 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV55945783, COSV55950122; called by muse, mutect2
- ABCB1 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV55959329; called by muse, mutect2, varscan2
- ABCB5 | c.2129C>T p.S710F (on ENST00000404938 / NM_001163941.2; = p.S265F on NM_178559.6) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51703687; called by muse, varscan2
- ABCC5 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV55587517; called by muse, mutect2, varscan2
- ABCC6 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs763591743, COSV52741571; called by mutect2, varscan2
- ABCC9 | c.3892G>A p.D1298N | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV53971768, COSV99687155; called by muse, mutect2
- ABCC9 | c.3891G>A p.M1297I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99687158; called by muse, mutect2
- ABCC9 | c.2527G>A p.D843N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53963637; called by mutect2, varscan2
- ABCG2 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52943544; called by muse, mutect2, varscan2
- ABCG2 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52943560; called by muse, mutect2, varscan2
- ABHD8 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as COSV99395559; called by mutect2, varscan2
- ABL2 | c.2324C>T p.S775F (on ENST00000502732 / NM_007314.4; = p.S760F on NM_005158.5) | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); catalogued as rs1557906215, COSV61011391; called by muse, mutect2
- ABL2 | c.1934C>T p.T645I (on ENST00000502732 / NM_007314.4; = p.T630I on NM_005158.5) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as COSV100772980; called by muse, mutect2, varscan2
- AC006059.2 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs755531878, COSV59605863; called by muse, mutect2, varscan2
- AC013489.1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as COSV51550257; called by muse, mutect2, varscan2
- ACAD10 | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as COSV58154282; called by muse, mutect2, varscan2
- ACE | c.950G>A p.W317* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs1414333467, COSV52003707; called by muse, mutect2, varscan2
- ACSL1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99860927; called by muse, mutect2, varscan2
- ACSL5 | c.571G>A p.A191T (on ENST00000354273; = p.A247T on NM_016234.3) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV61129002; called by muse, mutect2, varscan2
- ACSM2B | c.1625G>A p.R542K | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100313119, COSV61656919; called by muse, mutect2, varscan2
- ACTN2 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV63972409; called by muse, mutect2
- ACTRT1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs778684498, COSV64418975; called by muse, mutect2, varscan2
- ADAD1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV56641542; called by muse, mutect2
- ADAMDEC1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs868610362, COSV56474181; called by muse, mutect2, varscan2
- ADAMTS12 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs780005218, COSV61256390; called by muse, mutect2, varscan2
- ADAMTS14 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763213695, COSV64599858; called by mutect2, varscan2
- ADAMTS2 | c.3457G>A p.E1153K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs868859368, COSV52365685; called by muse, mutect2
- ADAMTS6 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV66857214; called by muse, mutect2, varscan2
- ADAMTS9 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV55775738; called by muse, mutect2
- ADCY8 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV53897699; called by muse, mutect2
- ADGRB1 | c.2317A>G p.I773V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.416); catalogued as COSV60092341; called by muse, mutect2, varscan2
- ADGRD1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV55439703; called by muse, mutect2, varscan2
- ADGRF2 | c.386G>A p.G129E (on ENST00000296862 / NM_001368115.2; = p.G61E on NM_153839.7) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57286647; called by muse, mutect2, varscan2
- ADGRF2 | c.1196C>T p.S399F (on ENST00000296862 / NM_001368115.2; = p.S331F on NM_153839.7) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.449); catalogued as rs867827781, COSV57286239, COSV57286655; called by muse, mutect2, varscan2
- ADGRG4 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV54950418; called by muse, mutect2, varscan2
- ADGRG4 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV54950427, COSV54961829; called by muse, mutect2, varscan2
- ADGRG4 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54950436; called by muse, mutect2, varscan2
- ADGRG4 | c.3941C>T p.S1314L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs751562884, COSV54950446; called by muse, mutect2, varscan2
- ADGRL2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752679138, COSV54649550; called by muse, mutect2, varscan2
- ADGRV1 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67979218; called by muse, mutect2, varscan2
- ADGRV1 | c.10595G>A p.W3532* | Nonsense Mutation (SNP) | VAF 32/295 reads (11%) | catalogued as COSV67979221; called by muse, mutect2, varscan2
- ADH1A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 69/339 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV52924354; called by muse, mutect2, varscan2
- AGBL1 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs937732927, COSV66849815; called by muse, mutect2
- AGBL1 | c.2416G>A p.G806R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66849824; called by muse, mutect2, varscan2
- AGL | c.1921C>T p.L641F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54048554; called by muse, mutect2, varscan2
- AGRN | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65067968; called by muse, mutect2, varscan2
- AHNAK | c.6301A>G p.K2101E | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV57204825; called by muse, mutect2, varscan2
- AKAP13 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV63449457; called by muse, mutect2, varscan2
- AKAP13 | c.5620C>T p.P1874S (on ENST00000394518 / NM_007200.5; = p.P1878S on NM_006738.6) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63449470; called by muse, mutect2, varscan2
- AKAP6 | c.6184G>A p.E2062K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55206082; called by muse, mutect2, varscan2
- AKAP9 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV62339593; called by muse, mutect2, varscan2
- AKNAD1 | c.1440G>A p.M480I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62195263; called by muse, mutect2, varscan2
- AL121899.2 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368238578; called by mutect2, varscan2
- AL121899.2 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs768372829, COSV101198683; called by mutect2, varscan2
- ALDH1L1 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56411101; called by mutect2, varscan2
- ALDH5A1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62372849; called by muse, mutect2
- ALMS1 | c.4562C>T p.P1521L | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV52503720; called by muse, mutect2
- ALPK2 | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV64490496; called by muse, mutect2, varscan2
- AMBRA1 | c.3554G>A p.S1185N (on ENST00000458649 / NM_001367468.1; = p.S1095N on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV54049282; called by muse, mutect2, varscan2
- AMER3 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs776199208, COSV100366963, COSV58465327; called by mutect2, varscan2
- AMER3 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs761116059, COSV58465334; called by mutect2, varscan2
- AMOTL1 | c.2368C>A p.P790T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100504732; called by mutect2, varscan2
- AMOTL1 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100504733; called by muse, mutect2, varscan2
- AMPH | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57733867; called by muse, mutect2, varscan2
- AMPH | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57733895; called by muse, mutect2, varscan2
- AMY2B | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 32/635 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63714177; called by muse, mutect2
- ANGPT4 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.107); catalogued as COSV101124872; called by muse, mutect2, varscan2
- ANGPTL4 | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56844358; called by muse, mutect2
- ANGPTL5 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1194008209, COSV57532006, COSV57532484; called by muse, varscan2
- ANK1 | c.4244G>A p.G1415D | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV55873942; called by muse, mutect2
- ANK1 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as COSV55873958; called by muse, mutect2, varscan2
- ANK3 | c.8927C>T p.P2976L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV55045759; called by mutect2, varscan2
- ANK3 | c.3455G>A p.G1152E (on ENST00000280772 / NM_001320874.2; = p.G286E on NM_001149.3) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55045770, COSV99778098; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.3850A>C p.N1284H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51841200; called by muse, mutect2, varscan2
- ANKRD11 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56355666; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.172); catalogued as COSV62003770; called by muse, mutect2
- ANKRD40 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV53317730; called by muse, mutect2, varscan2
- ANLN | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV56074143; called by muse, mutect2
- ANO2 | c.964G>A p.D322N (on ENST00000356134 / NM_001278597.3; = p.D326N on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs781540782, COSV59007575; called by mutect2, varscan2
- ANO3 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs756076284, COSV56781830; called by muse, mutect2, varscan2
- ANO5 | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV61082420; called by muse, mutect2, varscan2
- ANPEP | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs371057081; called by mutect2, varscan2
- ANXA10 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.687); catalogued as rs200407221; called by muse, mutect2, varscan2
- AOC1 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs560992275, COSV62867097; called by mutect2, varscan2
- AP1M2 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.824); catalogued as COSV51565568; called by muse, mutect2, varscan2
- AP2B1 | c.611T>A p.I204N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV51997334; called by muse, mutect2, varscan2
- APOL6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs780403475, COSV68749391; called by muse, mutect2, varscan2
- AR | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as rs750324117, CM035613, COSV65953437, COSV65963147; called by mutect2, varscan2
- ARAP1 | c.814G>A p.E272K (on ENST00000393609 / NM_001040118.2; = p.E27K on NM_015242.4) | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV61989625; called by muse, mutect2
- ARHGAP36 | c.1107C>T p.V369= | Splice Region (SNP) | VAF 31/167 reads (19%) | catalogued as COSV52264378; called by muse, mutect2, varscan2
- ARHGAP44 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs267604747, COSV52389603, COSV52405088; called by mutect2, varscan2
- ARHGEF1 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as COSV61526420; called by muse, varscan2
- ARHGEF15 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283998273, COSV62724435; called by muse, mutect2, varscan2
- ARHGEF17 | c.4985C>T p.S1662F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55235952; called by muse, mutect2, varscan2
- ARHGEF2 | c.2755C>T p.H919Y (on ENST00000361247 / NM_001162383.2; = p.H891Y on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV100561154; called by mutect2, varscan2
- ARHGEF5 | c.4684C>T p.P1562S | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50207887; called by muse, mutect2
- ARID4A | c.1903G>A p.G635S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV62162177; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by mutect2, varscan2
- ARMC8 | c.1045C>T p.H349Y (on ENST00000469044 / NM_001363941.2; = p.H335Y on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.196); catalogued as COSV61767726; called by muse, mutect2, varscan2
- ARSF | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63839044; called by muse, mutect2, varscan2
- ART3 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61913166; called by muse, mutect2, varscan2
- ASAH2 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.145); catalogued as COSV61482850; called by muse, mutect2, varscan2
- ASPM | c.6925C>T p.L2309F | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV54125318; called by muse, mutect2
- ASPM | c.5537C>T p.S1846F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV54125325, COSV99659410; called by muse, varscan2
- ASTN1 | c.2588G>A p.G863D | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56062335, COSV56078151; called by muse, mutect2, varscan2
- ATAD3C | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV58019484; called by muse, mutect2
- ATF4 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs34854854, COSV57477680, COSV99046520; called by muse, mutect2, varscan2
- ATG4A | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV58964421; called by muse, mutect2, varscan2
- ATP10D | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs935415055, COSV56704274; called by muse, mutect2, varscan2
- ATP10D | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV56704288; called by muse, mutect2, varscan2
- ATP10D | c.4028G>A p.R1343K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56687015; called by muse, mutect2, varscan2
- ATP11A | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52106636, COSV99369333; called by muse, mutect2, varscan2
- ATP12A | c.1747A>T p.T583S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV54512812; called by muse, mutect2, varscan2
- ATP12A | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54512825; called by muse, mutect2
- ATP23 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV55685493; called by muse, mutect2, varscan2
- ATP2B1 | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53804270; called by muse, mutect2
- ATP2B2 | c.2342C>T p.S781F (on ENST00000352432; = p.S747F on NM_001683.5) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59490335; called by mutect2, varscan2
- ATP2B3 | c.1862G>A p.G621D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1569534815, COSV54841094; called by muse, mutect2, varscan2
- ATP8A1 | c.2467G>A p.G823S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52529492; called by muse, varscan2
- ATP8B2 | c.1418C>T p.P473L (on ENST00000672630; = p.P440L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV59244880; called by muse, mutect2, varscan2
- ATP8B4 | c.77T>G p.F26C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV52709921; called by muse, mutect2
- ATP9A | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58763597; called by muse, mutect2, varscan2
- ATR | c.6371A>G p.K2124R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100638576; called by muse, mutect2, varscan2
- ATRX | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV64872135; called by muse, mutect2, varscan2
- AXIN2 | c.606T>A p.S202R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100196926; called by muse, mutect2, varscan2
- AXIN2 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100196771; called by muse, mutect2, varscan2
- AZIN2 | c.754-1G>A p.X252_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as COSV53855941, COSV99613087; called by muse, mutect2, varscan2
- B4GALT2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1389541267, COSV100530946; called by muse, mutect2, varscan2
- BAAT | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773128969, COSV52287359; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371554829, COSV100260142; called by muse, mutect2, varscan2
- BCAN | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV100228483; called by muse, mutect2, varscan2
- BCAN | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100228485; called by muse, mutect2, varscan2
- BCR | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs778656993, COSV59927499; called by muse, mutect2, varscan2
- BGN | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV100525175, COSV59035987; called by muse, mutect2, varscan2
- BLNK | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV56409160; called by muse, mutect2
- BMS1 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as COSV65732937; called by muse, mutect2
- BNIP5 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.132); catalogued as COSV71325326; called by muse, mutect2, varscan2
- BPGM | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV61323975; called by muse, mutect2, varscan2
- BRINP3 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV66514606; called by muse, mutect2, varscan2
- BRPF3 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as COSV60206171; called by muse, mutect2, varscan2
- BRWD3 | c.4918C>T p.H1640Y | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV64744300; called by muse, varscan2
- BTBD11 | c.2191G>A p.D731N (on ENST00000280758 / NM_001018072.2; = p.D268N on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.862); catalogued as COSV55017940; called by muse, mutect2, varscan2
- BTG3 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.641); catalogued as COSV60286152; called by muse, mutect2, varscan2
- BTN1A1 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV55066692; called by muse, mutect2
- BUD13 | c.612G>T p.R204S | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV52767194; called by muse, mutect2, varscan2
- C12orf40 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV61129657; called by muse, mutect2
- C14orf39 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV58779764; called by muse, mutect2, varscan2
- C15orf39 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV62295830; called by muse, mutect2
- C1RL | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as COSV56923600; called by muse, mutect2, varscan2
- C1orf87 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs1235526947, COSV64596166; called by muse, mutect2
- C1orf94 | c.1621C>T p.P541S (on ENST00000488417 / NM_001134734.2; = p.P351S on NM_032884.5) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV64913054; called by muse, mutect2, varscan2
- C1orf94 | c.1759C>T p.P587S (on ENST00000488417 / NM_001134734.2; = p.P397S on NM_032884.5) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1336220566, COSV64913063; called by muse, mutect2, varscan2
- C20orf194 | c.1810C>T p.L604F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV52691951; called by mutect2, varscan2
- C3orf20 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV53782738; called by muse, mutect2, varscan2
- C3orf62 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs780386279, COSV57985348; called by mutect2, varscan2
- C6orf118 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs199710080, COSV57812764; called by muse, mutect2, varscan2
- C8A | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs147003861, COSV100776456; called by muse, mutect2, varscan2
- C8B | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64776600; called by muse, mutect2, varscan2
- CABIN1 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV99573991; called by mutect2, varscan2
- CACNA1D | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV55438674; called by mutect2, varscan2
- CACNA1S | c.4841G>A p.R1614K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as rs1234083777, COSV62936614; called by muse, mutect2, varscan2
- CACNA2D1 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV62373636, COSV62384607; called by muse, varscan2
- CACNG6 | c.671G>A p.G224D (on ENST00000252729 / NM_145814.1; = p.G153D on NM_031897.2) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53165805; called by muse, mutect2, varscan2
- CAMK2D | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.136); catalogued as rs987657983, COSV56426469; called by muse, mutect2, varscan2
- CAMK2D | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV56426494; called by muse, mutect2, varscan2
- CAPN9 | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55230847; called by muse, mutect2, varscan2
- CASP14 | c.177+1G>A p.X59_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | catalogued as COSV55664861; called by muse, mutect2, varscan2
- CASR | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.537); catalogued as COSV56134023; called by muse, mutect2, varscan2
- CASS4 | c.2003G>A p.R668K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64385483; called by muse, mutect2
- CATSPERB | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV56422541; called by muse, mutect2, varscan2
- CATSPERB | c.2357G>A p.S786N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.158); catalogued as COSV56422560; called by mutect2, varscan2
- CAV1 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as COSV61952625; called by muse, mutect2, varscan2
- CBLN3 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52158937; called by muse, mutect2, varscan2
- CC2D2A | c.4253A>T p.Y1418F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.624); catalogued as COSV67502363; called by muse, mutect2, varscan2
- CCDC47 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.637); catalogued as COSV56721882, COSV56724677; called by muse, mutect2, varscan2
- CCDC69 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as rs769766241, COSV62599101; called by mutect2, varscan2
- CCDC73 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1462940314, COSV58795902; called by muse, mutect2, varscan2
- CCDC93 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60119722; called by muse, mutect2
- CCIN | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV58724127; called by muse, mutect2
- CD163 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.85); catalogued as COSV100776196, COSV63129860; called by muse, mutect2
- CD33 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV51800141; called by muse, mutect2, varscan2
- CD33 | c.747G>A p.G249= | Splice Region (SNP) | VAF 8/72 reads (11%) | catalogued as COSV51800159, COSV51800208; called by muse, mutect2
- CD48 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV63566054; called by muse, mutect2, varscan2
- CD8B | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58928456; called by muse, mutect2
- CDC42BPA | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV62003488; called by muse, mutect2
- CDC42BPG | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV61345730; called by muse, mutect2, varscan2
- CDH26 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770653358, COSV54843208; called by mutect2, varscan2
- CDH4 | c.1024A>C p.T342P | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV64643096; called by muse, mutect2
- CDH4 | c.2215C>T p.L739F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64643101; called by muse, mutect2, varscan2
- CDON | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs761798261, COSV54995443; called by muse, mutect2, varscan2
- CEACAM18 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67282229; called by muse, varscan2
- CELSR3 | c.7054C>T p.R2352* | Nonsense Mutation (SNP) | VAF 16/139 reads (12%) | catalogued as COSV50840836; called by mutect2, varscan2
- CENPE | c.4523C>T p.S1508L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.386); catalogued as COSV54376765; called by muse, mutect2, varscan2
- CENPE | c.2615C>T p.T872I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54376776; called by muse, mutect2, varscan2
- CEP104 | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as COSV65516284; called by muse, mutect2
- CEP104 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV65516289; called by mutect2, varscan2
- CEP112 | c.1298A>T p.K433I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV67136502; called by muse, mutect2, varscan2
- CEP192 | c.1907T>G p.M636R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58060475, COSV58063871; called by muse, mutect2, varscan2
- CEP192 | c.3239C>T p.A1080V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs943191806, COSV100382102; called by muse, mutect2, varscan2
- CEP250 | c.6758G>A p.G2253E | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs749167005, COSV61168458; called by muse, mutect2, varscan2
- CEP350 | c.2882C>T p.S961F | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV62599116; called by muse, mutect2
- CER1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV66602927; called by muse, varscan2
- CFAP161 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54428350; called by mutect2, varscan2
- CFAP298-TCP10L | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as rs1448722556, COSV55828447; called by muse, mutect2
- CFAP52 | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV55343094, COSV55346175; called by muse, mutect2, varscan2
- CFAP54 | c.7007C>T p.S2336L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV61570851; called by mutect2, varscan2
- CFAP92 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV54046147; called by muse, mutect2
- CFH | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs761698279, COSV62776388; called by muse, mutect2, varscan2
- CFH | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV66406049, COSV66411551; called by muse, mutect2, varscan2
- CFH | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.322); catalogued as rs867229260, COSV66406054; called by muse, varscan2
- CFHR1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV57626219; called by muse, mutect2, varscan2
- CFHR2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV100804371, COSV66380555; called by muse, mutect2, varscan2
- CGNL1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV55563946; called by muse, varscan2
- CHD2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100560888; called by muse, mutect2, varscan2
- CHD2 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1381374225, COSV59119150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD5 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99314988; called by mutect2, varscan2
- CHD6 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58554239; called by muse, mutect2
- CHD7 | c.6710C>T p.S2237F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV71107436; called by muse, mutect2, varscan2
- CHD9 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV68297190; called by muse, mutect2
- CHM | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100753631; called by muse, mutect2, varscan2
- CHODL | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV54731342; called by muse, varscan2
- CHST15 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV60560467; called by muse, mutect2
- CHSY1 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54251559; called by muse, mutect2, varscan2
- CILP | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.45); catalogued as COSV56022177; called by muse, mutect2, varscan2
- CIPC | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV62376714; called by muse, mutect2, varscan2
- CLCA4 | c.2206G>A p.G736R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778586168, COSV65282503; called by muse, mutect2, varscan2
- CLCNKB | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs1432964196, COSV65159764; called by muse, mutect2
- CLEC14A | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV60561819; called by mutect2, varscan2
- CLEC4E | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55225024; called by muse, mutect2, varscan2
- CLEC4E | c.37+1G>A p.X13_splice | Splice Site (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100222749; called by muse, mutect2, varscan2
- CLMN | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54179369; called by muse, mutect2, varscan2
- CNGA2 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs369362557, COSV61703409; called by muse, mutect2, varscan2
- CNTN5 | c.3050G>A p.G1017D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.86); PolyPhen probably damaging (1); catalogued as COSV54284663; called by muse, mutect2, varscan2
- CNTN6 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs199898905, COSV63163128, COSV63179673; called by muse, mutect2, varscan2
- CNTNAP2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.464); catalogued as COSV62148931; called by muse, mutect2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2
- CNTNAP3 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as COSV52664256; called by muse, varscan2
- COL17A1 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs760109253, COSV62225412; called by muse, mutect2, varscan2
- COL1A1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV56802815; called by muse, mutect2, varscan2
- COL20A1 | c.3422G>A p.G1141E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766208108, COSV58912333; called by mutect2, varscan2
- COL2A1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.999); catalogued as COSV61528162; called by muse, mutect2, varscan2
- COL4A1 | c.2814G>A p.M938I | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); catalogued as COSV65421952; called by muse, mutect2, varscan2
- COL4A1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65421963; called by muse, mutect2, varscan2
- COL4A2 | c.3062G>A p.G1021E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64625209; called by muse, mutect2, varscan2
- COL4A3 | c.3382G>A p.G1128S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59257517; called by muse, mutect2, varscan2
- COL6A6 | c.4400G>A p.G1467E | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763083321, COSV62018791; called by muse, mutect2, varscan2
- COL9A1 | c.2656C>T p.P886S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV57879288; called by muse, mutect2, varscan2
- COLEC12 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68368717; called by muse, mutect2, varscan2
- COLGALT2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.259); catalogued as rs751007014, COSV100730861; called by mutect2, varscan2
- COX20 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV63673042; called by muse, mutect2, varscan2
- CP | c.1036+1G>A p.X346_splice | Splice Site (SNP) | VAF 7/84 reads (8%) | catalogued as COSV99224465; called by muse, mutect2
- CPAMD8 | c.4567G>A p.G1523R (on ENST00000651564; = p.G1476R on NM_015692.5) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.469); catalogued as rs758169336, COSV71595838; called by mutect2, varscan2
- CPXM2 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.025); catalogued as rs370358833; called by muse, varscan2
- CR1 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100887855; called by muse, mutect2
- CR1 | c.5372G>A p.G1791E | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.073); catalogued as COSV65456158; called by muse, mutect2
- CR2 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs764276175, COSV65506205; called by muse, varscan2
- CRB1 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV66328805; called by muse, varscan2
- CREB3L2 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV57792432; called by muse, mutect2
- CRK | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs1223714291, COSV56029796; called by muse, mutect2, varscan2
- CRYBG2 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV57483994; called by muse, mutect2
- CSE1L | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs372508022; called by mutect2, varscan2
- CSMD2 | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53883842; called by muse, mutect2, varscan2
- CSMD3 | c.6496G>A p.E2166K (on ENST00000297405 / NM_001363185.1; = p.E2062K on NM_052900.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52111116; called by muse, mutect2
- CSMD3 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV52111132; called by muse, mutect2, varscan2
- CST5 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1268595833, COSV59013936; called by muse, mutect2
- CT83 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs782474980, COSV64140804; called by muse, varscan2
- CTNNA3 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV57717320; called by muse, mutect2, varscan2
- CTNND2 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757438938, COSV58868058; called by muse, mutect2, varscan2
- CUX2 | c.4432C>T p.R1478W | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1295475797, COSV55625454; called by muse, mutect2, varscan2
- CWH43 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV56936319; called by muse, mutect2, varscan2
- CX3CR1 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as rs373233918, COSV64193181; called by muse, mutect2, varscan2
- CXCR2 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs200127100, COSV59279841; called by mutect2, varscan2
- CYLC1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as rs1236706921, COSV61410187; called by muse, mutect2, varscan2
- CYLD | c.1123T>G p.W375G | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs1182344095, COSV61093158; called by muse, mutect2, varscan2
- CYP19A1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs770120065, COSV53057383; called by mutect2, varscan2
- CYP1A2 | c.1398G>A p.W466* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV59659111; called by muse, mutect2, varscan2
- CYP24A1 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53773054; called by muse, mutect2
- CYP2B6 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV57842612; called by muse, mutect2, varscan2
- CYP2C9 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV53246829; called by muse, mutect2, varscan2
- CYP2C9 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV53246436; called by muse, mutect2
- CYP3A4 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs540702483, COSV60501047; called by mutect2, varscan2
- CYP3A7 | c.29A>G p.E10G | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs1226046422, COSV60480623; called by muse, mutect2, varscan2
- CYP4A22 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV53738432; called by muse, mutect2, varscan2
- CYP4F12 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV100215526; called by muse, mutect2, varscan2
- CYTH3 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV63437519, COSV63439111; called by muse, mutect2, varscan2
- DACT1 | c.2352G>A p.W784* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100242111; called by muse, mutect2
- DAO | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV57321510; called by muse, mutect2
- DAXX | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV99802637; called by muse, mutect2, varscan2
- DCST1 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55056784; called by muse, varscan2
- DCTN1 | c.2369C>T p.S790L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV62619725; called by mutect2, varscan2
- DDX46 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV62798563; called by muse, mutect2, varscan2
- DDX50 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV65291773; called by muse, mutect2, varscan2
- DDX60L | c.4199C>T p.S1400F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52709522; called by muse, mutect2, varscan2
- DECR1 | c.378C>G p.N126K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV55167025; called by mutect2, varscan2
- DENND6B | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV63784451; called by muse, mutect2
- DENND6B | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs200196394; called by muse, mutect2, varscan2
- DESI2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55640223; called by muse, mutect2
- DGAT2L6 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.323); catalogued as rs147349994, COSV60717185; called by muse, mutect2, varscan2
- DGKI | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as rs142003962; called by mutect2, varscan2
- DHX34 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.248); catalogued as COSV60894479; called by muse, mutect2, varscan2
- DHX8 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV52251148; called by muse, mutect2, varscan2
- DICER1 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.842); catalogued as rs1222748384, COSV58616079; called by muse, mutect2, varscan2
- DIO2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766634398, COSV70444816; called by muse, mutect2, varscan2
- DISP1 | c.3163C>T p.H1055Y | Missense Mutation (SNP) | VAF 46/655 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52655177; called by muse, mutect2
- DLK1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs774427009, COSV57990680; called by mutect2, varscan2
- DMBT1 | c.5383G>A p.D1795N (on ENST00000338354 / NM_001377530.1; = p.D1038N on NM_004406.3) | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760683143, COSV57535850, COSV57547017; called by muse, mutect2, varscan2
- DMBT1 | c.7502C>T p.S2501F (on ENST00000338354 / NM_001377530.1; = p.S1744F on NM_004406.3) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57535893; called by muse, mutect2, varscan2
- DMD | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as CM114838, COSV63736810; called by muse, mutect2, varscan2
- DMRT1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV66519189; called by mutect2, varscan2
- DNAAF5 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99860295; called by muse, mutect2, varscan2
- DNAH10 | c.6913C>T p.R2305* (on ENST00000409039; = p.R2244* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV69000416; called by muse, mutect2
- DNAH11 | c.4242G>A p.M1414I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV60941708; called by mutect2, varscan2
- DNAH17 | c.4116G>A p.V1372= | Splice Region (SNP) | VAF 23/58 reads (40%) | catalogued as rs758951397, COSV101101646, COSV67750172; called by muse, mutect2, varscan2
- DNAH17 | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV101103661, COSV67750176; called by muse, mutect2, varscan2
- DNAH2 | c.2360C>T p.A787V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV66716830; called by mutect2, varscan2
- DNAH2 | c.11855G>A p.G3952D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66716833; called by muse, mutect2, varscan2
- DNAH3 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.077); catalogued as COSV54505908; called by muse, mutect2
- DNAH5 | c.9139G>A p.E3047K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54206416; called by muse, mutect2, varscan2
- DNAH5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs779957324, COSV54206424; called by muse, mutect2, varscan2
- DNAH7 | c.3512G>A p.R1171Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746376803, COSV56753545, COSV56758533; called by mutect2, varscan2
- DNAH9 | c.7244G>A p.G2415E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867370987, COSV52336049; called by muse, mutect2, varscan2
- DNAH9 | c.13425G>A p.W4475* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV52336063; called by muse, mutect2
- DNAJB14 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62032821; called by muse, mutect2
- DNER | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV59160744; called by muse, mutect2, varscan2
- DNMBP | c.4580G>A p.R1527Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450724397, COSV60621068; called by muse, mutect2
- DNMT1 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV61576768; called by muse, varscan2
- DNPEP | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs901680919, COSV56110180; called by muse, mutect2, varscan2
- DNPEP | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1182494773, COSV56110187; called by muse, mutect2, varscan2
- DOCK10 | c.5246C>T p.S1749F | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV51350293; called by muse, mutect2, varscan2
- DOK5 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.932); catalogued as COSV52817022; called by muse, mutect2, varscan2
- DOP1A | c.3508T>A p.S1170T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.01); catalogued as COSV52707215; called by muse, mutect2, varscan2
- DOP1A | c.7078C>T p.R2360W | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52707227; called by muse, mutect2, varscan2
- DOP1B | c.2444C>T p.S815F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV101215834; called by muse, mutect2, varscan2
- DPH6 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1273260594, COSV56612827; called by muse, mutect2
- DPPA3 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV61502763; called by muse, mutect2, varscan2
- DPT | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.655); catalogued as COSV63189600; called by muse, mutect2, varscan2
- DPYD | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV64591675, COSV64594672; called by muse, mutect2, varscan2
- DQX1 | c.710G>A p.W237* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as rs764272497, COSV66352974; called by muse, mutect2, varscan2
- DRP2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV65809347; called by muse, mutect2, varscan2
- DSC3 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV64571815; called by muse, mutect2, varscan2
- DSG4 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV57388732; called by muse, mutect2, varscan2
- DUOX1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220433843, COSV58477763; called by muse, mutect2, varscan2
- DUSP10 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs780562110, COSV60456677; called by muse, mutect2, varscan2
- E2F1 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV58534510; called by muse, mutect2, varscan2
- ECD | c.1705-1G>A p.X569_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100624773, COSV100624863; called by muse, mutect2, varscan2
- ECHDC3 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV64867296; called by muse, mutect2, varscan2
- ECM1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100682281; called by muse, mutect2
- EDNRA | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV60095844, COSV60099103; called by muse, mutect2, varscan2
- EDRF1 | c.1903C>T p.P635S (on ENST00000356792 / NM_001202438.2; = p.P601S on NM_015608.2) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100523985; called by muse, mutect2, varscan2
- EDRF1 | c.1904C>T p.P635L (on ENST00000356792 / NM_001202438.2; = p.P601L on NM_015608.2) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs899525654; called by mutect2, varscan2
- EEF1AKMT1 | c.456A>C p.K152N | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV66964409; called by muse, mutect2
- EFCAB5 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); catalogued as COSV57926487; called by muse, mutect2, varscan2
- EFCAB5 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1237989456, COSV57926494; called by muse, mutect2, varscan2
- EFCAB7 | c.1880T>C p.L627P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1472864754, COSV64314005; called by muse, mutect2, varscan2
- EFEMP1 | c.81G>A p.T27= | Splice Region (SNP) | VAF 10/89 reads (11%) | catalogued as COSV62615170; called by muse, mutect2, varscan2
- EFS | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.1); catalogued as COSV53731295; called by muse, mutect2
- EGF | c.2720G>A p.G907E | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs901322091, COSV54476029; called by muse, mutect2
- EHBP1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV50416231; called by muse, mutect2, varscan2
- EHD3 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV59029358; called by muse, mutect2, varscan2
- EHMT1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV58371325; called by muse, mutect2, varscan2
- EIF2AK3 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as rs866676281, COSV57545247; called by muse, mutect2
- EIF3H | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs540738471, COSV52664247; called by mutect2, varscan2
- EIF4G3 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV51675035; called by muse, mutect2, varscan2
- ELAVL4 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV63914688; called by muse, mutect2
- ELF3 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs1258691938, COSV62837353; called by muse, mutect2, varscan2
- ELMO1 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs781351975, COSV60296432; called by mutect2, varscan2
- ELN | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1164562093, COSV52707312; called by muse, mutect2, varscan2
- ELOVL3 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV64174172; called by muse, mutect2, varscan2
- ENAM | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865873089, COSV68535306; called by muse, mutect2
- ENKUR | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV58632454; called by muse, mutect2, varscan2
- ENO1 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.388); catalogued as COSV52302855, COSV52305494; called by muse, mutect2, varscan2
- ENPEP | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV104371909, COSV54447414; called by muse, mutect2, varscan2
- ENPP1 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV62930385; called by muse, mutect2, varscan2
- EPC2 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.99); catalogued as COSV51540777; called by muse, mutect2, varscan2
- EPHA3 | c.2445G>A p.W815* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | catalogued as COSV60695403; called by muse, mutect2
- EPHA4 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.776); catalogued as COSV56027253; called by muse, mutect2, varscan2
- EPHA5 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV56629373; called by muse, mutect2, varscan2
- EPHB1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV67654867; called by muse, mutect2
- EPO | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 11/150 reads (7%) | catalogued as rs893404064, COSV53161061; called by muse, mutect2
- EPS8L3 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV62608803; called by muse, mutect2, varscan2
- ERC2 | c.2807G>A p.G936E | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV55603394; called by muse, mutect2
- ERC2 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV55603408; called by muse, mutect2, varscan2
- ERG | c.1075G>A p.G359R (on ENST00000398919 / NM_001243428.1; = p.G335R on NM_004449.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55727644; called by muse, mutect2, varscan2
- ERV3-1 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV51426267; called by muse, mutect2, varscan2
- ESRP1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 47/447 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs769966537, COSV64408013, COSV64413091; called by muse, mutect2, varscan2
- ETV3 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100461171; called by muse, varscan2
- EVI5 | c.1444A>C p.K482Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV64825698; called by muse, mutect2
- EVPL | c.5935G>A p.E1979K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as rs575377469, COSV56907768; called by mutect2, varscan2
- EVPL | c.4489C>T p.R1497W | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373960086; called by muse, mutect2, varscan2
- EXD2 | c.676C>T p.R226C (on ENST00000312994 / NM_001193362.1; = p.R101C on NM_018199.3) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs762151815, COSV57278078, COSV57278257; called by mutect2, varscan2
- EXD2 | c.871C>T p.P291S (on ENST00000312994 / NM_001193362.1; = p.P166S on NM_018199.3) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100473999, COSV57278280; called by muse, mutect2, varscan2
- EXO1 | c.282-1G>A p.X94_splice | Splice Site (SNP) | VAF 21/85 reads (25%) | catalogued as COSV62216528; called by muse, mutect2, varscan2
- EYA4 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV62046399; called by muse, mutect2, varscan2
- F13B | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs759996311, COSV66372444; called by mutect2, varscan2
- F5 | c.4022C>T p.P1341L | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV63121081; called by muse, mutect2, varscan2
- F5 | c.3382C>T p.Q1128* | Nonsense Mutation (SNP) | VAF 13/144 reads (9%) | catalogued as COSV63121087, COSV63128995; called by muse, mutect2
- F8A1 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100371818, COSV100371827; called by muse, mutect2
- F9 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs867548424, COSV54378854; called by muse, mutect2, varscan2
- FAAH2 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66505676; called by muse, mutect2, varscan2
- FAM151A | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56363092; called by muse, mutect2, varscan2
- FAM153B | c.661G>A p.E221K (on ENST00000253490; = p.E144K on NM_001265615.1) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.141); catalogued as rs763674695, COSV53685372, COSV53688864; called by mutect2, varscan2
- FAM160B1 | c.1459C>T p.L487F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV65087379; called by muse, mutect2, varscan2
- FAM161B | c.997G>A p.E333K (on ENST00000651776; = p.E270K on NM_152445.3) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs565392148, COSV54101112; called by mutect2, varscan2
- FAM168B | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV66303657; called by muse, mutect2, varscan2
- FAM171A1 | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV65313662; called by muse, mutect2
- FAM184A | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV58851879; called by muse, mutect2, varscan2
- FAM193A | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as rs1474030075, COSV61191259; called by muse, mutect2, varscan2
- FAM227B | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54805260, COSV54806246; called by muse, varscan2
- FAM71A | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1202368321, COSV99674886; called by muse, mutect2, varscan2
- FAM71A | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV54234713; called by muse, mutect2, varscan2
- FAM76B | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.441); catalogued as rs774635263, COSV62556091; called by mutect2, varscan2
- FAT4 | c.11761C>T p.P3921S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV58671775; called by muse, mutect2, varscan2
- FBN2 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs1364065855, COSV52495086; called by mutect2, varscan2
- FBN3 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs149936210; called by mutect2, varscan2
- FCAR | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV62028522; called by muse, mutect2, varscan2
- FCGR2A | c.196C>T p.R66C (on ENST00000271450 / NM_001136219.3; = p.R65C on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1257003455, COSV54837274; called by muse, mutect2, varscan2
- FCGR3A | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV63458952; called by muse, mutect2, varscan2
- FCRL6 | c.125G>A p.W42* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV58940055; called by muse, varscan2
- FERMT1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54090904; called by muse, mutect2, varscan2
- FERMT2 | c.1138A>G p.K380E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs764477726, COSV58405347; called by mutect2, varscan2
- FGD6 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59690674; called by muse, mutect2, varscan2
- FGF12 | c.584C>T p.S195L (on ENST00000454309 / NM_021032.5; = p.S133L on NM_004113.6) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.311); catalogued as COSV53154169; called by muse, varscan2
- FGF14 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65936565; called by muse, mutect2, varscan2
- FHL5 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs138154376, COSV58735765; called by mutect2, varscan2
- FKBP6 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs1216896736, COSV52719022; called by muse, mutect2, varscan2
- FKTN | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV56308342, COSV56312246; called by muse, mutect2, varscan2
- FLAD1 | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); catalogued as rs1376131292, COSV52695937; called by muse, mutect2, varscan2
- FLG | c.5884G>A p.E1962K | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs766766888, COSV64237362; called by muse, mutect2
- FLG | c.4735G>A p.G1579R | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.425); catalogued as rs866974362, COSV64237368; called by muse, mutect2
- FLG2 | c.3857A>G p.H1286R | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV66166874; called by muse, mutect2
- FLG2 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV66166879; called by muse, mutect2
- FLNC | c.4693G>A p.D1565N | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57966933; called by muse, mutect2, varscan2
- FNBP4 | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99771975; called by muse, mutect2, varscan2
- FNDC1 | c.5206C>T p.H1736Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.049); catalogued as COSV51931575; called by muse, mutect2, varscan2
- FOSB | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV62278420; called by muse, mutect2, varscan2
- FOXL2NB | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.9); PolyPhen probably damaging (0.948); catalogued as COSV57725794; called by muse, mutect2, varscan2
- FPR3 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as rs374854764; called by muse, mutect2, varscan2
- FPR3 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs1232784401, COSV59328194; called by mutect2, varscan2
- FREM1 | c.1253G>A p.W418* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV63087157; called by muse, mutect2
- FRMD7 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV53744815; called by muse, mutect2, varscan2
- FRMPD4 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66211688; called by muse, mutect2, varscan2
- FRRS1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV54920625; called by muse, mutect2
- FTL | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV53169167; called by muse, varscan2
- FUT5 | c.442T>C p.F148L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53134968; called by muse, mutect2, varscan2
- FYB2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV58583120; called by mutect2, varscan2
- FZD6 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs143405641; called by mutect2, varscan2
- GABRB3 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV54651835; called by muse, mutect2, varscan2
- GABRQ | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs782766146, COSV64780696; called by muse, mutect2, varscan2
- GALNT17 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61149366; called by muse, mutect2, varscan2
- GALNTL6 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.444); catalogued as COSV101560580; called by muse, mutect2, varscan2
- GALNTL6 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs377525077; called by muse, mutect2, varscan2
- GALP | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61999264; called by muse, mutect2, varscan2
- GART | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV67818076; called by mutect2, varscan2
- GAS7 | c.1345C>T p.R449* (on ENST00000432992 / NM_201433.2; = p.R309* on NM_003644.3) | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as rs779994808, COSV60432176; called by mutect2, varscan2
- GBE1 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1405930755, COSV70097232; called by muse, mutect2, varscan2
- GCSAML | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63577169; called by mutect2, varscan2
- GDF10 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781809828; called by muse, mutect2
- GET3 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1398649782, COSV62001918; called by muse, varscan2
- GFI1B | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59743775; called by muse, mutect2, varscan2
- GH2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60426375; called by muse, mutect2, varscan2
- GIMAP5 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57529673; called by muse, mutect2, varscan2
- GIMAP6 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV61032590; called by muse, mutect2, varscan2
- GJA5 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs953262342, COSV54783048; called by muse, mutect2, varscan2
- GJB3 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV64904416; called by muse, mutect2
- GLB1L2 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV56995292; called by muse, mutect2, varscan2
- GNAQ | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV54107778; called by muse, mutect2, varscan2
- GNAS | c.222A>T p.E74D | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.237); catalogued as COSV55671776, COSV55674711; called by muse, mutect2, varscan2
- GNB3 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV51831249; called by muse, mutect2, varscan2
- GNB5 | c.941G>A p.R314K (on ENST00000261837 / NM_016194.4; = p.R272K on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as rs966112783, COSV55897936; called by muse, mutect2, varscan2
- GON4L | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs776601913, COSV55187733; called by mutect2, varscan2
- GPC5 | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1267676418, COSV65579755; called by mutect2, varscan2
- GPR161 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV54787981; called by muse, mutect2, varscan2
- GPR20 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs772120190, COSV66683967; called by muse, mutect2, varscan2
- GPR39 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV61421404; called by muse, mutect2
- GPSM2 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 52/572 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV51441141, COSV51443588; called by muse, mutect2
- GRB7 | c.1309T>C p.S437P | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV58446510; called by muse, mutect2
- GRID1 | c.2909C>T p.S970L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs1345667117, COSV60015605, COSV60044886; called by mutect2, varscan2
- GRID2 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56176895; called by muse, mutect2
- GRIN2A | c.4058G>A p.R1353K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV58021897; called by muse, mutect2, varscan2
- GRIN2A | c.3026G>A p.R1009K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58021927; called by muse, varscan2
- GRIN2A | c.2809G>A p.D937N | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.5); catalogued as rs769602505, COSV58021938; called by muse, varscan2
- GRIN3A | c.2224G>A p.G742R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62451151; called by muse, varscan2
- GRXCR1 | c.829T>C p.C277R | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67670283; called by muse, mutect2
- GTF3C1 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55174282; called by muse, mutect2, varscan2
- GUCY2F | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as rs1358614377, COSV54298952; called by muse, mutect2, varscan2
- HAS2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392190, COSV58264318; called by muse, mutect2, varscan2
- HBD | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs528751190, COSV53082024; called by muse, mutect2, varscan2
- HCFC1 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV60069717; called by muse, mutect2, varscan2
- HDAC9 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.829); catalogued as COSV67767779; called by mutect2, varscan2
- HDAC9 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV67767795; called by muse, mutect2, varscan2
- HEATR3 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1180418409, COSV53528240; called by muse, mutect2, varscan2
- HEATR4 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58569849, COSV58570183; called by muse, mutect2, varscan2
- HEATR6 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV51743897; called by muse, mutect2, varscan2
- HEPH | c.3194G>A p.R1065Q (on ENST00000343002; = p.R798Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs187860440, COSV57958684, COSV57959706; called by mutect2, varscan2
- HFM1 | c.4096C>T p.Q1366* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | catalogued as COSV54022104; called by muse, mutect2, varscan2
- HHIPL2 | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 56/636 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58563364; called by muse, mutect2
- HIPK1 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.056); catalogued as COSV61246221; called by muse, mutect2, varscan2
- HIPK4 | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV52519462; called by muse, mutect2, varscan2
- HIVEP2 | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs757993303, COSV50005956; called by mutect2, varscan2
- HIVEP3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.074); catalogued as COSV56010190; called by muse, mutect2, varscan2
- HJV | c.986G>A p.R329Q (on ENST00000336751 / NM_213653.4; = p.R216Q on NM_145277.5) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs782614415, COSV60951119; called by mutect2, varscan2
- HM13 | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV59435838; called by muse, mutect2, varscan2
- HMCN1 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99635446; called by muse, mutect2, varscan2
- HMCN1 | c.13135C>T p.P4379S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99635450; called by muse, varscan2
- HMGCS2 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 48/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65567281; called by muse, mutect2
- HNF4G | c.964C>T p.Q322* (on ENST00000354370 / NM_001330561.2; = p.Q369* on NM_004133.5) | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV62966038; called by muse, varscan2
- HNRNPCL1 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58610173; called by muse, mutect2, varscan2
- HNRNPCL1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV58610180; called by muse, mutect2
- HNRNPCL1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs777968727, COSV58610187; called by muse, mutect2, varscan2
- HNRNPL | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99670556; called by mutect2, varscan2
- HNRNPL | c.268-1G>A p.X90_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99670557; called by muse, mutect2, varscan2
- HPSE2 | c.1321-1G>A p.X441_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as COSV65181545, COSV65192119; called by muse, mutect2, varscan2
- HTN1 | c.72G>A p.K24= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55894646; called by muse, mutect2, varscan2
- HTR5A | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1359995825, COSV55280803; called by muse, mutect2, varscan2
- HTR5A | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV55280821, COSV99840092; called by muse, mutect2, varscan2
- IBSP | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56894772; called by muse, mutect2
- IBTK | c.3683C>T p.S1228F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); catalogued as COSV60391104; called by muse, mutect2, varscan2
- ICA1 | c.607A>T p.K203* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV55576434; called by mutect2, varscan2
- IDO2 | c.1207C>T p.L403F (on ENST00000389060; = p.L416F on NM_194294.2) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58423845; called by muse, mutect2, varscan2
- IDS | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.029); catalogued as COSV61711352; called by muse, mutect2, varscan2
- IFNA8 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1301213662, COSV66504305; called by muse, mutect2, varscan2
- IFNLR1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 13/120 reads (11%) | catalogued as rs1223318062, COSV59525289; called by muse, mutect2, varscan2
- IFT122 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs770572794, COSV56200171; called by mutect2, varscan2
- IFT140 | c.3756C>A p.N1252K | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63697414; called by muse, varscan2
- IGF2R | c.319T>A p.S107T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100808155; called by muse, mutect2, varscan2
- IGF2R | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100808156; called by mutect2, varscan2
- IGFBP7 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.525); catalogued as rs1243260590, COSV55271707; called by mutect2, varscan2
- IGFN1 | c.2357G>A p.G786E (on ENST00000295591 / NM_001367841.1; = p.G3243E on NM_001164586.2) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55166993; called by mutect2, varscan2
- IGHG4 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs373601578; called by muse, mutect2
- IGHV3-20 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as rs1180033400; called by muse, mutect2, varscan2
- IGHV3-23 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); catalogued as rs575212512; called by muse, mutect2
- IL10RA | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV57139820; called by muse, mutect2, varscan2
- IL13RA1 | c.829-1G>A p.X277_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as rs1397187678, COSV65424195; called by muse, mutect2
- ILDR1 | c.953C>T p.S318F (on ENST00000344209 / NM_001199799.2; = p.S274F on NM_175924.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56548114; called by muse, mutect2, varscan2
- ILDR2 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV54828839, COSV54828951; called by muse, mutect2, varscan2
- INHA | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV54713437; called by muse, mutect2, varscan2
- INPP5B | c.914C>T p.S305F (on ENST00000373023; = p.S225F on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV65959577; called by muse, mutect2, varscan2
- INSRR | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as rs201715497, COSV63871157; called by mutect2, varscan2
- INTS14 | c.503C>T p.S168F (on ENST00000313182 / NM_001366360.2; = p.S89F on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs775342994, COSV57525764, COSV57528453; called by muse, mutect2, varscan2
- INTS3 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1479646638, COSV59675382; called by muse, mutect2
- INTS3 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as COSV99670166; called by muse, mutect2
- INTS7 | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV65343729; called by muse, mutect2, varscan2
- INTS7 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.217); catalogued as COSV65343731; called by muse, mutect2, varscan2
- IQCH | c.2380G>A p.V794M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs998675550, COSV60049498; called by muse, mutect2, varscan2
- IQGAP1 | c.4646G>A p.R1549K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV51581892; called by muse, mutect2
- ISG20L2 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as rs1039529717, COSV57459464, COSV57459473; called by muse, mutect2
- ITGA3 | c.2257A>T p.T753S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV50306291; called by muse, mutect2, varscan2
- ITGA4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.922); catalogued as rs200678526, COSV51998107; called by mutect2, varscan2
- ITGA5 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as rs754755879, COSV53215801; called by muse, mutect2, varscan2
- ITGBL1 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.995); catalogued as COSV66005645; called by muse, mutect2, varscan2
- ITIH2 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756461788, COSV64432804; called by mutect2, varscan2
- ITPR3 | c.2931C>T p.F977= | Splice Region (SNP) | VAF 35/226 reads (15%) | catalogued as COSV65406156; called by muse, mutect2, varscan2
- ITSN1 | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66081000; called by muse, mutect2
- IYD | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs376472194; called by mutect2, varscan2
- JAM2 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748367121, COSV57255678; called by mutect2, varscan2
- JAML | c.79C>T p.P27S (on ENST00000356289 / NM_001098526.2; = p.P17S on NM_153206.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99409741; called by muse, mutect2, varscan2
- JARID2 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs1316410441, COSV59185823; called by muse, mutect2, varscan2
- JPH1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60608876; called by muse, mutect2
- KANK4 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV100587388, COSV62985555; called by muse, mutect2, varscan2
- KAT7 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52013286, COSV52013499; called by mutect2, varscan2
- KAZN | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63206849; called by muse, mutect2
- KBTBD3 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV73241245; called by muse, mutect2
- KBTBD7 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65266116; called by muse, mutect2, varscan2
- KCNA10 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63904250; called by muse, mutect2, varscan2
- KCNB1 | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV65566296; called by muse, mutect2, varscan2
- KCNB2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV73048821; called by muse, mutect2
- KCNH7 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59786691; called by muse, mutect2, varscan2
- KCNIP3 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54666049, COSV54673710; called by mutect2, varscan2
- KCNIP4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs1393043312, COSV62845882; called by muse, mutect2, varscan2
- KCNK16 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949137, COSV64677293; called by muse, mutect2, varscan2
- KCNK5 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63988620; called by muse, varscan2
- KCTD16 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV72576870; called by muse, mutect2
- KCTD6 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs1468365531, COSV57147785; called by muse, mutect2, varscan2
- KCTD7 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV51876178; called by muse, mutect2, varscan2
- KEL | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62333518; called by muse, mutect2, varscan2
- KERA | c.617A>T p.N206I | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV57129956; called by muse, mutect2, varscan2
- KERA | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV57129967; called by muse, varscan2
- KIAA0319 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65496589; called by muse, mutect2, varscan2
- KIAA0408 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100847076, COSV64105196; called by muse, mutect2, varscan2
- KIAA1191 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV100055583; called by muse, mutect2, varscan2
- KIAA1191 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as COSV100055587; called by muse, mutect2, varscan2
- KIF1B | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV55804060; called by muse, mutect2, varscan2
- KIF25 | c.1022C>T p.S341F (on ENST00000354419 / NM_030615.2; = p.S289F on NM_005355.3) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63026615; called by muse, mutect2, varscan2
- KIF26B | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63637036; called by muse, mutect2, varscan2
- KIF2B | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 6/83 reads (7%) | catalogued as COSV52127427; called by muse, mutect2
- KL | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66307980; called by muse, mutect2, varscan2
- KLF9 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as COSV65807350; called by muse, mutect2, varscan2
- KLHL12 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV66127011; called by muse, mutect2, varscan2
- KLHL7 | c.709C>T p.L237F (on ENST00000339077 / NM_001031710.3; = p.L189F on NM_018846.5) | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59159968; called by muse, mutect2
- KLK5 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60450638; called by muse, mutect2, varscan2
- KLK5 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550878265, COSV100307214; called by mutect2, varscan2
- KLK5 | c.500A>T p.K167I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.313); catalogued as COSV60449603; called by mutect2, varscan2
- KLK7 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100304351, COSV58343944; called by muse, mutect2, varscan2
- KMO | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.119); catalogued as COSV63807592, COSV63810623; called by muse, mutect2
- KMT2D | c.2602C>G p.P868A | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV56414054; called by muse, mutect2, varscan2
- KMT2D | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as COSV56414065; called by muse, mutect2, varscan2
- KRT17 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60860037; called by muse, mutect2, varscan2
- KRT17 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as rs367544262, CM1313136; called by muse, mutect2, varscan2
- KRT31 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433582; called by muse, mutect2
- KRT79 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100398558; called by muse, mutect2, varscan2
- KRTAP12-4 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV59953357; called by muse, mutect2, varscan2
- KRTAP13-3 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV61878640; called by muse, mutect2, varscan2
- KRTAP15-1 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1388172270, COSV61877076; called by muse, mutect2
- L3MBTL1 | c.1351C>T p.L451F (on ENST00000418998 / NM_001377303.1; = p.L361F on NM_015478.7) | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV64227941; called by muse, varscan2
- L3MBTL4 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV53114365; called by muse, mutect2
- LAIR2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375622805, COSV56620829; called by muse, mutect2, varscan2
- LAMB4 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52714068; called by muse, mutect2, varscan2
- LAMC2 | c.3337C>T p.L1113F | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51452727; called by muse, mutect2
- LAYN | c.373T>C p.Y125H (on ENST00000375615 / NM_001258390.1; = p.Y117H on NM_178834.5) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65104459; called by muse, mutect2, varscan2
- LCP1 | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV59939606; called by muse, mutect2, varscan2
- LGALS4 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV57042811; called by muse, mutect2, varscan2
- LGI2 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV66122419; called by muse, mutect2, varscan2
- LGR6 | c.1739G>A p.G580E (on ENST00000367278 / NM_001017403.1; = p.G528E on NM_021636.3) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV55152145; called by muse, mutect2, varscan2
- LGSN | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs144073733, COSV65726321; called by muse, mutect2, varscan2
- LIFR | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV54685208; called by muse, mutect2, varscan2
- LILRB1 | c.127G>A p.V43I (on ENST00000427581; = p.V7I on NM_006669.6) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV61116184; called by muse, varscan2
- LILRB1 | c.1367C>T p.S456L (on ENST00000427581; = p.S420L on NM_006669.6) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs148543880, COSV61116186; called by muse, mutect2, varscan2
- LILRB1 | c.1606C>T p.R536* (on ENST00000427581; = p.R486* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as rs754376189, COSV61116188; called by muse, mutect2, varscan2
- LIMCH1 | c.1732C>A p.P578T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100574385; called by mutect2, varscan2
- LIMCH1 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100574389, COSV58295646; called by muse, mutect2, varscan2
- LIMCH1 | c.3097C>T p.L1033F | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV58274706; called by muse, mutect2
- LIPG | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99724738; called by muse, mutect2, varscan2
- LMO2 | c.304C>T p.R102C (on ENST00000395833 / NM_001142315.2; = p.R171C on NM_005574.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1438345549, COSV57645538; called by muse, mutect2, varscan2
- LMX1A | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV54217355; called by muse, mutect2, varscan2
- LNX1 | c.1822G>A p.D608N (on ENST00000263925 / NM_001126328.3; = p.D512N on NM_032622.2) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); catalogued as COSV55782446, COSV55788635; called by muse, mutect2, varscan2
- LPIN2 | c.1182A>C p.R394S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55237571; called by muse, mutect2
- LPXN | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67716168; called by muse, mutect2, varscan2
- LRBA | c.7958G>A p.G2653E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764223120, COSV63950263, COSV63950447; called by mutect2, varscan2
- LRP12 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52625966; called by muse, mutect2, varscan2
- LRRC15 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.309); catalogued as rs185381044, COSV61649564; called by muse, mutect2, varscan2
- LRRC32 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs757556414, COSV52631689; called by mutect2, varscan2
- LRRC49 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs371609494, COSV53008263; called by muse, mutect2, varscan2
- LRRC52 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54231155; called by muse, mutect2, varscan2
- LRRC66 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV58632227; called by muse, mutect2, varscan2
- LRRIQ3 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV63041484; called by mutect2, varscan2
- LRRIQ3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs866672669, COSV63041491; called by muse, mutect2, varscan2
- LRRIQ3 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs867456281, COSV63041497, COSV63046665; called by muse, mutect2, varscan2
- LRRIQ4 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as rs1338461074, COSV100540044, COSV61618693; called by muse, varscan2
- LRRN1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.437); catalogued as COSV60012539; called by muse, mutect2, varscan2
- LRRN2 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1157892356, COSV65783276; called by muse, mutect2, varscan2
- LRRTM3 | c.385T>C p.F129L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63661999; called by muse, mutect2, varscan2
- LTBP2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56205450; called by muse, mutect2, varscan2
- LTK | c.2461C>T p.Q821* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV53026661; called by muse, mutect2
- LY6G6D | c.15T>G p.F5L | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101010846; called by muse, mutect2
- LYSMD2 | c.428T>G p.F143C | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.408); catalogued as COSV51056671; called by muse, mutect2
- LYST | c.9362A>T p.N3121I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV67703708; called by muse, mutect2, varscan2
- LZTR1 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309568769, COSV53145725, COSV99302293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MACF1 | c.6481C>T p.P2161S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV57108316; called by muse, mutect2, varscan2
- MACF1 | c.21806C>T p.P7269L (on ENST00000372915; = p.P5314L on NM_012090.5) | Missense Mutation (SNP) | VAF 12/121 reads (10%) | catalogued as COSV57108337; called by muse, mutect2
- MAEL | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV63303969; called by muse, mutect2, varscan2
- MAGEA12 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV100757046; called by muse, mutect2, varscan2
- MAGEB18 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV57463434, COSV57463517; called by muse, mutect2, varscan2
- MAGEC1 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV53568650; called by muse, mutect2
- MAGEC2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV55997948; called by muse, mutect2, varscan2
- MAGI1 | c.3161G>A p.G1054E (on ENST00000402939 / NM_001033057.2; = p.G1083E on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58315653; called by muse, mutect2, varscan2
- MAMDC2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65856776; called by muse, mutect2, varscan2
- MAOB | c.1205T>C p.F402S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65204374; called by muse, varscan2
- MAOB | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV65204382; called by muse, mutect2, varscan2
- MAP1A | c.7064A>C p.E2355A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV55806438; called by muse, mutect2, varscan2
- MAP2 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs144486691; called by mutect2, varscan2
- MAP3K10 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV53420614; called by muse, mutect2
- MAP3K14 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60922770; called by muse, mutect2, varscan2
- MAP3K3 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51991233; called by muse, mutect2, varscan2
- MAP3K4 | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs143918593; called by mutect2, varscan2
- MAP4K4 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV56325783; called by muse, mutect2, varscan2
- MAP7D1 | c.2173T>C p.S725P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV60215178; called by muse, mutect2
- MAPK14 | c.142T>A p.L48I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV57694786; called by muse, mutect2
- MARCHF11 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV60126335; called by muse, mutect2, varscan2
- MARCKSL1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs374147732; called by muse, mutect2, varscan2
- MARF1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.017); catalogued as rs1409092127, COSV60020254; called by muse, mutect2, varscan2
- MAST2 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV100788752; called by muse, mutect2, varscan2
- MC3R | c.639T>G p.F213L | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1338499934, COSV54763108; called by muse, mutect2
- MCF2L2 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61049740; called by muse, mutect2, varscan2
- MCTP2 | c.1062G>A p.W354* | Nonsense Mutation (SNP) | VAF 12/116 reads (10%) | catalogued as COSV59141215; called by muse, mutect2, varscan2
- MDGA1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51792229; called by muse, mutect2, varscan2
- MDH1B | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417209575, COSV65588638; called by muse, mutect2, varscan2
- MECOM | c.692C>T p.S231F (on ENST00000468789 / NM_001105078.4; = p.S419F on NM_004991.4) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449004579, COSV52960269; called by muse, mutect2, varscan2
- MED9 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV99245898; called by mutect2, varscan2
- MEI1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55901093; called by muse, mutect2, varscan2
- MFSD6L | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV61001518; called by muse, mutect2, varscan2
- MGAM | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs753437264, COSV72073746; called by muse, mutect2
- MGAT4A | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53845507; called by muse, mutect2
- MIA3 | c.5647G>A p.G1883S | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs1349371442, COSV60510215; called by muse, mutect2
- MIER2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.444); catalogued as rs755036267, COSV53394219; called by muse, varscan2
- MIER2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs780727112, COSV53394228; called by muse, varscan2
- MINDY4 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.543); catalogued as rs1269632033, COSV54671471, COSV99519202; called by muse, mutect2, varscan2
- MKKS | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV61398052; called by muse, mutect2, varscan2
- MLIP | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.481); catalogued as rs368458090; called by mutect2, varscan2
- MME | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as COSV64706119; called by muse, mutect2
- MMP12 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV58259169; called by muse, mutect2
- MMP27 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV52779891; called by muse, mutect2, varscan2
- MMP9 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV64884282; called by muse, mutect2, varscan2
- MNDA | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755462956, COSV63739993; called by mutect2, varscan2
- MON2 | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as COSV54802721; called by muse, mutect2, varscan2
- MPDU1 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | catalogued as rs1187782942, COSV99549242; called by muse, mutect2, varscan2
- MRFAP1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100307686; called by muse, mutect2, varscan2
- MS4A5 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as COSV55740006; called by muse, mutect2, varscan2
- MSANTD4 | c.721del p.R241Gfs*3 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | catalogued as COSV57285534; called by mutect2, pindel, varscan2
- MSL3 | c.1284C>T p.V428= (on ENST00000312196 / NM_078629.4; = p.V262= on NM_006800.4) | Splice Region (SNP) | VAF 14/55 reads (25%) | catalogued as COSV56491792; called by muse, mutect2, varscan2
- MST1R | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV56565129; called by muse, mutect2, varscan2
- MTAP | c.433T>G p.C145G | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV66476992; called by muse, mutect2, varscan2
- MTRR | c.570A>G p.I190M (on ENST00000264668; = p.I163M on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52941902; called by muse, mutect2
- MTTP | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55504053; called by muse, mutect2, varscan2
- MTUS2 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV70914046; called by mutect2, varscan2
- MUC16 | c.27344C>T p.S9115L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV67447652; called by mutect2, varscan2
- MUC16 | c.21869C>T p.S7290F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.109); catalogued as rs1479427786, COSV67447658, COSV67494696; called by muse, varscan2
- MUC16 | c.20969C>T p.S6990F | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1218923660, COSV67447665; called by muse, mutect2
- MUC16 | c.7208C>T p.S2403F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1357636577, COSV67447684; called by muse, mutect2, varscan2
- MUC17 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV60281150; called by muse, mutect2, varscan2
- MUC17 | c.12116C>T p.S4039F | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV60281158; called by muse, mutect2
- MUC3A | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); catalogued as rs1453794380; called by muse, mutect2, varscan2
- MUC4 | c.14899G>A p.G4967R (on ENST00000463781 / NM_018406.7; = p.G731R on NM_004532.6) | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV57769095; called by muse, mutect2
- MUC4 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.934); catalogued as COSV62134219; called by muse, mutect2, varscan2
- MUCL3 | c.1462G>A p.D488N (on ENST00000304311; = p.D1364N on NM_080870.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs769351075, COSV58516271; called by mutect2, varscan2
- MVK | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1052942178, COSV57330989; called by muse, mutect2, varscan2
- MXRA5 | c.3275C>T p.S1092F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs868133596, COSV54225203; called by muse, mutect2, varscan2
- MYCBP2 | c.8480C>T p.P2827L (on ENST00000357337; = p.P2865L on NM_015057.5) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.987); catalogued as rs1430587535, COSV62011197; called by muse, mutect2
- MYCBP2 | c.8036G>A p.G2679E (on ENST00000357337; = p.G2717E on NM_015057.5) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.023); catalogued as COSV62011206; called by muse, mutect2, varscan2
- MYH1 | c.4882G>A p.E1628K | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV56844122; called by muse, mutect2, varscan2
- MYH1 | c.4571G>A p.G1524E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV56844131; called by muse, mutect2, varscan2
- MYH1 | c.2867A>C p.K956T | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99876843; called by muse, mutect2
- MYH10 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV52595630; called by mutect2, varscan2
- MYH11 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); catalogued as COSV55544295; called by muse, mutect2
- MYH13 | c.4322C>T p.T1441I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV52821637, COSV99078179; called by muse, mutect2, varscan2
- MYH4 | c.4871G>A p.G1624E | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs778455809, COSV55113012; called by muse, mutect2, varscan2
- MYH4 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs199624888, COSV99702200; called by muse, mutect2, varscan2
- MYH4 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs939415421, COSV55113039; called by muse, mutect2
- MYH6 | c.5065G>A p.E1689K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV62448128; called by muse, mutect2, varscan2
- MYH6 | c.1892-1G>A p.X631_splice | Splice Site (SNP) | VAF 9/67 reads (13%) | catalogued as rs1392570969, COSV62448131; called by muse, mutect2, varscan2
- MYH6 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV62448138; called by muse, mutect2, varscan2
- MYH7 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs868440817, COSV62516589; called by muse, mutect2, varscan2
- MYH8 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101238771, COSV67961308; called by muse, mutect2
- MYO15A | c.7207G>A p.D2403N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as CS102209, COSV52752457; called by muse, mutect2, varscan2
- MYO18A | c.5176G>A p.A1726T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV62862830; called by muse, mutect2
- MYO18B | c.7174G>A p.D2392N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV59126532; called by muse, mutect2, varscan2
- MYO1D | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV59007975; called by muse, mutect2
- MYO5B | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53212145; called by muse, mutect2, varscan2
- MYO5C | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs767085005, COSV55897940; called by muse, mutect2, varscan2
- MYO5C | c.2551C>T p.R851* | Nonsense Mutation (SNP) | VAF 16/151 reads (11%) | catalogued as rs200841357, COSV55902979; called by mutect2, varscan2
1,373 further variants in this file (622 protein-altering or splice-affecting, 708 silent, 43 other) are not listed here.
